TCGA case TCGA-DD-AACC — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ed8c0d53-5db0-4b77-95ec-15971926e313

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: South Korea; Age at index: 61 years; Vital status: Dead; Days to death: 1,685 days (4.6 years).

Diagnoses (2)
1. Combined hepatocellular carcinoma and cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8180/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 61.6 years (22,499 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Combined hepatocellular carcinoma and cholangiocarcinoma), site: Liver. Age at diagnosis: 63.1 years (23,036 days); Days to diagnosis: 537 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 537 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Liver; Days to recurrence: 537 days (1.5 years).
- Days to follow up: 1,685 days (4.6 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Albumin 3.9 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.8; Blood test normal range upper: 5.3].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 1; Blood test normal range upper: 1].
- Alpha Fetoprotein 24 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8].
- Creatinine 1.3 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.5].
- Platelets 208 (unit not recorded by GDC) [Blood test normal range lower: 130; Blood test normal range upper: 400].
- Total Bilirubin 0.5 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.2].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 61 kg; Height: 165 cm; BMI: 22.4.
- Timepoint category: Prior to Diagnosis; Risk factors: Hepatitis B Infection.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-AACC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-DD-AACC-01A-01-TS1: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 78; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 20; Percent lymphocyte infiltration: 22; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-DD-AACC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-AACC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; Hepatic inflammation adj tissue: Mild.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,685 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,685 days; disease-free interval: event (new tumor event after initially disease-free), 537 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 537 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-AACC-01A-11D-A40Q-01): tumor purity 0.31, ploidy 1.98, whole-genome doublings 0.
